Somatic mutation profile of tumor specimen 0DY1R5 from CCDI case PBCRLH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 3.4 years (1,233 days).
Specimen 0DY1R5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e94f0610-ca51-42d7-9d9d-148439754247.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY1QJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5de856b3-15d2-431e-a434-984db84aadcd

The open-access MAF lists 62 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 10, Intron 4, Nonsense Mutation 2, 3'UTR 2, Translation Start Site 1, 3'Flank 1, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 272/308 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 192/1037 reads (19%) | catalogued as rs1463609963, COSV54124703; called by muse, mutect2, varscan2
- DICER1 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 338/790 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58615244, COSV58615703, COSV58615881; called by muse, mutect2, varscan2
- FANCB | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 176/1213 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs770865662; called by muse, mutect2, varscan2
- GK2 | c.1088C>G p.A363G | Missense Mutation (SNP) | VAF 28/880 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1198190142; called by muse, mutect2
- GLMN | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 293/751 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs777680500; called by muse, mutect2, varscan2
- NOD2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 289/609 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs983465914; called by muse, mutect2, varscan2
- OR10J3 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 27/1042 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV59954160, COSV59955312; called by muse, mutect2
- OR9A4 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 497/546 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs535851431, COSV71885566, COSV71886048; called by muse, mutect2, varscan2
- PCARE | c.3137G>T p.R1046L | Missense Mutation (SNP) | VAF 138/454 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs752697018, COSV100527855; called by muse, mutect2, varscan2
- PROSER3 | c.1009C>G p.R337G | Missense Mutation (SNP) | VAF 162/332 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780180435; called by muse, mutect2, varscan2
- RALGAPA1 | c.4447C>T p.R1483* | Nonsense Mutation (SNP) | VAF 350/775 reads (45%) | catalogued as rs1482528601, COSV51876093; called by muse, mutect2, varscan2
- REC114 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 282/697 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750349868, COSV58523843; called by muse, mutect2, varscan2
- TTLL6 | c.1901C>A p.T634K (on ENST00000393382 / NM_001130918.3; = p.T327K on NM_173623.3) | Missense Mutation (SNP) | VAF 122/691 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV64977448; called by muse, mutect2, varscan2
- ZBTB44 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 32/1163 reads (3%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as rs973230352; called by muse, mutect2
- ACAN | c.2466G>C p.E822D | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AHNAK | c.8552G>T p.G2851V | Missense Mutation (SNP) | VAF 20/600 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ALDOC | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 803/1340 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTG3 | c.359A>T p.K120I | Missense Mutation (SNP) | VAF 32/888 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 37/1207 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CFH | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 378/1078 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, mutect2
- CSMD3 | c.5596G>T p.V1866F (on ENST00000297405 / NM_001363185.1; = p.V1762F on NM_052900.3) | Missense Mutation (SNP) | VAF 36/1138 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- DST | c.19306A>T p.S6436C (on ENST00000361203 / NM_001374722.1; = p.S4133C on NM_015548.5) | Missense Mutation (SNP) | VAF 47/906 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- EML5 | c.5834G>A p.G1945D (on ENST00000380664; = p.G1953D on NM_183387.3) | Missense Mutation (SNP) | VAF 116/1032 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FCGBP | c.11692G>C p.A3898P | Missense Mutation (SNP) | VAF 131/543 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FRMD4A | c.1988C>G p.P663R | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- GLRA2 | c.394T>A p.L132M | Missense Mutation (SNP) | VAF 316/1130 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HAL | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 132/585 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- HAPLN3 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 315/684 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HIVEP3 | c.881A>C p.H294P | Missense Mutation (SNP) | VAF 226/514 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1586 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 228/540 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NOL7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 62/746 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); called by muse, mutect2
- NUP107 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 34/684 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OR8H2 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 44/1317 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- PLS3 | c.1202G>T p.R401I | Missense Mutation (SNP) | VAF 593/1060 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RAI2 | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 56/1337 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2
- RLIM | c.1324T>A p.S442T | Missense Mutation (SNP) | VAF 345/1222 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEC23B | c.691T>A p.F231I | Missense Mutation (SNP) | VAF 160/657 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SEMA3F | c.1336T>G p.Y446D | Missense Mutation (SNP) | VAF 103/462 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLAIN2 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 232/526 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SMU1 | c.725A>T p.N242I | Missense Mutation (SNP) | VAF 43/805 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TTLL8 | c.2153del p.S718Tfs*7 | Frame Shift Del (DEL) | VAF 84/98 reads (86%) | called by mutect2, varscan2
- TTLL8 | c.2152A>C p.S718R | Missense Mutation (SNP) | VAF 84/98 reads (86%) | SIFT tolerated (0.44); PolyPhen benign (0); called by mutect2, varscan2
- AGTR1 | c.354A>T p.L118= | Silent (SNP) | VAF 30/1160 reads (3%) | called by muse, mutect2
- DNAH17 | c.8535A>T p.I2845= | Silent (SNP) | VAF 130/707 reads (18%) | catalogued as COSV67752335; called by muse, mutect2, varscan2
- GPR45 | c.315C>T p.H105= | Silent (SNP) | VAF 131/706 reads (19%) | called by muse, mutect2, varscan2
- GPR75 | c.1458T>C p.Y486= | Silent (SNP) | VAF 291/779 reads (37%) | called by muse, mutect2, varscan2
- MUC22 | c.4866T>C p.R1622= | Silent (SNP) | VAF 402/922 reads (44%) | called by muse, mutect2, varscan2
- OR10H4 | c.861T>A p.L287= | Silent (SNP) | VAF 48/851 reads (6%) | called by muse, mutect2
- OR6J1 | c.489C>A p.S163= | Silent (SNP) | VAF 40/379 reads (11%) | called by muse, mutect2, varscan2
- PACS2 | c.2616G>T p.S872= | Silent (SNP) | VAF 32/672 reads (5%) | catalogued as COSV100330631; called by muse, mutect2
- PPP4R3C | c.1383A>G p.E461= | Silent (SNP) | VAF 52/1502 reads (3%) | called by muse, mutect2
- VIRMA | c.5163A>G p.G1721= | Silent (SNP) | VAF 86/943 reads (9%) | catalogued as COSV52582542; called by muse, mutect2
- CTXN2 | c.-529C>G | 5'UTR (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- DNAH3 | c.6601+31C>G | Intron (SNP) | VAF 149/334 reads (45%) | called by muse, mutect2, varscan2
- FRA10AC1 | c.*50T>A | 3'UTR (SNP) | VAF 22/610 reads (4%) | catalogued as rs1317249854; called by muse, mutect2
- GTF3AP5 | n.635A>G | RNA (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- NF2 | c.*99G>A | 3'UTR (SNP) | VAF 47/194 reads (24%) | called by muse, mutect2, varscan2
- PNCK | c.69-17C>T | Intron (SNP) | VAF 373/1320 reads (28%) | catalogued as rs782030016; called by muse, mutect2, varscan2
- POLD1 | c.590-32C>T | Intron (SNP) | VAF 74/281 reads (26%) | called by muse, mutect2, varscan2
- SMG1 | c.5841+49_5841+64del | Intron (DEL) | VAF 82/190 reads (43%) | called by mutect2, varscan2
- TAP2 | chr6:32822239 A>T | 3'Flank (SNP) | VAF 296/694 reads (43%) | called by muse, mutect2, varscan2
